Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4777, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4777-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

1: Kidney, right, partial nephrectomy:

DIAGNOSIS:

1. Kidney, right, partial nephrectomy::

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 1.9 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section diagnosis, labeled, "Right renal tumor (stitch marks deep margin)". It consists of a 4.7 x 3.9 x 3.8 cm specimen, including renal parenchyma, tumor and perirenal fat. Sectioning reveals a 1.9 cm tan-yellow, well-demarcated tumor, located 0.3 cm from the resection margin and approaching close to the renal capsule. The margin is inked and the specimen is submitted for frozen section diagnosis. A portion of tumor and kidney are submitted for TPS. Representative sections are submitted.

Summary of Sections:

FSC -- frozen section control

T -- tumor

TC -- tumor and capsule

NL -- normal

PRF -- perirenal fat

Summary of Sections:

Part 1: Kidney, right, partial nephrectomy:

Block	Sect. Site	PCs
1	fsc	1
1	nl	1
1	prf	1
3	t	3
1	tc	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM, MARGINS ARE FREE.
PERMANENT DIAGNOSIS: same

Source: NCI Genomic Data Commons file df9fde53-5ec0-403d-8568-10437f65c132 (TCGA-BP-4777.BB486BC7-F293-48BA-8343-D9813E6C5518.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).